Somatic mutation profile of tumor specimen 0DX0R5 from CCDI case PBCPZB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.3 years (835 days).
Specimen 0DX0R5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 686110b4-6a85-4055-a699-d2d002950dfd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX0Q9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a83b6049-f0fe-4117-82ed-d178dc57e90c

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIT | c.5741C>T p.P1914L | Missense Mutation (SNP) | VAF 35/414 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs1419651630; called by muse, mutect2
- COL8A2 | c.1573G>A p.G525R | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57440702; called by muse, mutect2, varscan2
- ATXN1L | c.1593G>A p.Q531= | Silent (SNP) | VAF 79/311 reads (25%) | catalogued as rs759445968; called by muse, mutect2, varscan2
